MMRF case MMRF_2290 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a7107e40-065a-47f6-a4ea-eb7ab9c906bb

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 79 years; Vital status: Dead; Days to death: 139 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 79.4 years (29,009 days); ISS stage: II; Days to last known disease status: 139 days; Days to last follow up: 139 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 139 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 14 days; Days to treatment end: 139 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 139.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 9 (ECOG 2): M Protein 5.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 18.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.231 mg/dL; Immunoglobulin G 95.3 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 3.3 µg/mL; Lactate Dehydrogenase 2.13 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.45 mmol/L; Albumin 33 g/L; Total Protein 12 g/dL; Glucose 5.94 mmol/L.
- Day 99 (ECOG 3): M Protein 1.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.843 mg/dL; Immunoglobulin G 24.7 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.29 mmol/L; Albumin 34 g/L; Total Protein 8.3 g/dL; Glucose 5.5 mmol/L.

Other clinical attributes
- Day 9: Weight: 63 kg; Height: 161 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.

Biospecimens (2 samples)
- Sample MMRF_2290_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 9 days.
- Sample MMRF_2290_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 9 days.
